Somatic mutation profile of tumor specimen MP2PRT-PASZEN-TMP1-A (aliquot MP2PRT-PASZEN-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASZEN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,896 days).
Specimen MP2PRT-PASZEN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a23b18e2-3bc1-48fc-9e48-8dcbfdc52220.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASZEN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASZEN-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5601e99-39fc-459f-9490-bba5ce7d8d1f

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NR5A1 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 82/414 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs375469069, CM080459; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.530C>A p.S177* | Nonsense Mutation (SNP) | VAF 152/386 reads (39%) | catalogued as COSV51843352; called by muse, mutect2, varscan2
- HDGFL3 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 177/430 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1446324632, COSV55207291; called by muse, mutect2, varscan2
- HEY2 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 360/775 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as rs1184794935, COSV64239858; called by muse, mutect2, varscan2
- KIAA1671 | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 221/505 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as rs1441252265; called by muse, mutect2, varscan2
- PCDH11X | c.2060C>A p.P687Q | Missense Mutation (SNP) | VAF 431/733 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV53456679, COSV53464294; called by muse, mutect2, varscan2
- TNMD | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 148/542 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs769813716; called by muse, mutect2, varscan2
- CDH7 | c.1609A>C p.K537Q | Missense Mutation (SNP) | VAF 72/171 reads (42%) | SIFT tolerated (1); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- FGF3 | c.444C>T p.S148= | Silent (SNP) | VAF 202/654 reads (31%) | catalogued as rs566764532; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1917T>C p.R639= | Silent (SNP) | VAF 171/425 reads (40%) | called by muse, mutect2, varscan2
